Gene-level copy-number profile of tumor specimen TCGA-02-0039-01A from TCGA case TCGA-02-0039, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 54.9 years (20,065 days).
Specimen TCGA-02-0039-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.06bf8847-2174-4bc0-befc-06437ca9ea29.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-02-0039-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/47d281ed-5ea7-4a6c-b7ab-6d75a30a6649

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 46; copy number 1: 12,988; copy number 2: 46,740; copy number 3: 34; copy number 12: 6; copy number 13: 2; copy number 14: 2; copy number 16: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-02-0039-01): tumor purity 0.61, ploidy 1.81, whole-genome doublings 0 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 46 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:71,182,612–73,354,276, 37 genes: RNU6-411P, AL589935.1, AL589935.3, AL589935.2, OGFRL1, AL136164.2, AL136164.1, LINC00472, MIR30C2, AL136164.3, MIR30A, LINC01626, AL035467.2, AL035467.1, KRT19P1, RNU4-66P, RIMS1, AL035633.1, FO393414.2, FO393414.1, FO393414.3, KCNQ5, MIR4282, KNOP1P4, PGAM1P10, KCNQ5-AS1, RBPMS2P1, KHDC1P1, AL365232.1, KHDC1L, KHDC1, AC019205.1, RPSAP41, EIF3EP1, SDCBP2P1, PAICSP3, DPPA5.
- chr10:87,751,512–88,049,823, 9 genes (within-gene range 0–1): ATAD1, CFL1P1, RN7SL78P, KLLN, PTEN, AC063965.2, RPL11P3, AC063965.1, MED6P1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 12 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:68,746,125–68,850,686, 6 genes, copy number 12 (within-gene range 2–12): SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2.
- chr12:80,561,017–80,593,701, 2 genes, copy number 16: AKIRIN1P1, AC074031.1.
- chr12:81,094,371–81,158,461, 2 genes, copy number 14: AC078955.1, MIR4699.
- chr12:127,933,689–128,027,166, 2 genes, copy number 13 (within-gene range 2–13): LINC00508, LINC02441.

Autosomal genes at a single copy (total copy number 1): 10,607. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
